Gene-level copy-number profile of tumor specimen TCGA-HU-A4G8-01A from TCGA case TCGA-HU-A4G8, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,254 days).
Specimen TCGA-HU-A4G8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.41c95a2f-4ffa-4a25-beed-10c862faef6b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4G8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/010b28c1-7a15-4534-8962-138901341a69

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,118; copy number 2: 53,637; copy number 3: 5,062.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4G8-01A-11D-A253-01): tumor purity 0.51, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
